Somatic mutation profile of tumor specimen TCGA-DU-7290-01A (aliquot TCGA-DU-7290-01A-11D-2024-08) from TCGA case TCGA-DU-7290, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 45.6 years (16,667 days).
Specimen TCGA-DU-7290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 277d158f-4cf9-4c38-b68b-36432901405b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7290-10A (Blood Derived Normal), aliquot TCGA-DU-7290-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89913d64-9f9b-4f5f-b9e3-2ca3943e1662

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 50/101 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782343, CM991080, COSV64290665, COSV64299259, COSV64307337; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF6 | c.145A>T p.M49L | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51696643; called by muse, mutect2, varscan2
- ARID1B | c.2376T>A p.Y792* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV51683634; called by muse, mutect2, varscan2
- CEACAM7 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 73/231 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs782608870, COSV50072669; called by muse, mutect2, varscan2
- CELSR3 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs754895348, COSV51170566; called by muse, mutect2, varscan2
- DMXL1 | c.4141A>T p.S1381C | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV60722445; called by muse, mutect2, varscan2
- EFNB3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs759236058, COSV56833542; called by muse, mutect2
- FBXL7 | c.1078T>A p.C360S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61654386; called by muse, mutect2, varscan2
- GDF6 | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV54628366; called by muse, mutect2, varscan2
- H2AC6 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58415220, COSV58417758; called by muse, mutect2, varscan2
- ICAM5 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.052); catalogued as COSV53427626; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1751T>G p.I584R | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV61186864; called by muse, mutect2, varscan2
- MED12 | c.4056C>A p.D1352E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV61358349; called by muse, mutect2, varscan2
- MYH13 | c.4579C>A p.L1527I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52835757, COSV52845283; called by muse, mutect2, varscan2
- OR1L8 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs748254512, COSV59186491; called by muse, mutect2, varscan2
- OR2B3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs761688447, COSV65851237; called by muse, mutect2, varscan2
- PACC1 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV54789990; called by muse, mutect2, varscan2
- PGM5 | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs201672908, COSV67168317; called by muse, mutect2, varscan2
- PIEZO2 | c.6988G>A p.V2330I | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs756549202, COSV53286661; called by muse, mutect2, varscan2
- PSG9 | c.709+1G>A p.X237_splice | Splice Site (SNP) | VAF 101/299 reads (34%) | catalogued as rs182343176, COSV52488988; called by muse, mutect2, varscan2
- RB1 | c.484_485del p.F162Qfs*8 | Frame Shift Del (DEL) | VAF 34/80 reads (43%) | catalogued as COSV57318017; called by mutect2, pindel, varscan2
- RET | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.366); catalogued as rs775086466, COSV60710532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGIP1 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.921); catalogued as rs747920514, COSV52773178, COSV52780406; called by muse, mutect2, varscan2
- STAB2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV66348306; called by muse, mutect2, varscan2
- TTN | c.7817C>T p.A2606V (on ENST00000591111; = p.A2560V on NM_003319.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | PolyPhen possibly damaging (0.823); catalogued as rs370857722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF429 | c.1927C>A p.H643N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100641743, COSV61919622; called by muse, mutect2, varscan2
- JAML | c.630G>C p.G210= (on ENST00000356289 / NM_001098526.2; = p.G200= on NM_153206.3) | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV52629991; called by muse, mutect2, varscan2
- MXRA5 | c.6726G>A p.P2242= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as rs182612819, COSV54253266; called by muse, mutect2, varscan2
- OTOP1 | c.432C>T p.T144= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs1197401216, COSV56397571; called by muse, mutect2, varscan2
- PRPF8 | c.636G>A p.P212= | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as rs143150486; called by muse, mutect2
- PTCHD4 | c.1716C>T p.I572= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV59799268; called by muse, mutect2, varscan2
- SYNE1 | c.2136A>G p.E712= (on ENST00000367255 / NM_182961.4; = p.E719= on NM_033071.3) | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV55122427; called by muse, mutect2, varscan2
- ZNF519 | c.168G>A p.E56= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV73913382; called by muse, mutect2, varscan2
